Somatic mutation profile of tumor specimen TCGA-E8-A414-01A (aliquot TCGA-E8-A414-01A-11D-A23M-08) from TCGA case TCGA-E8-A414, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 45.9 years (16,754 days).
Specimen TCGA-E8-A414-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc01a15d-ffcc-41e6-9ea6-ea49bf572f63.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E8-A414-10A (Blood Derived Normal), aliquot TCGA-E8-A414-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/954c2fd9-c599-4174-ac03-3fa02e1dcea6

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Splice Site 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- APOL5 | c.504G>A p.M168I | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV99968358; called by muse, mutect2, varscan2
- DDX23 | c.1382+1G>A p.X461_splice | Splice Site (SNP) | VAF 55/248 reads (22%) | catalogued as COSV100339756; called by muse, varscan2
- DOCK2 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.461); catalogued as COSV99911430; called by muse, mutect2
- KIF26B | c.3772C>T p.P1258S | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1442326418; called by muse, mutect2
- PIK3CD | c.931-2A>G p.X311_splice | Splice Site (SNP) | VAF 13/58 reads (22%) | catalogued as COSV100740078; called by muse, mutect2, varscan2
- SPTA1 | c.4039G>A p.A1347T | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.382); catalogued as COSV63756362; called by muse, mutect2, varscan2
- RTBDN | c.108C>A p.A36= (on ENST00000393233 / NM_001270444.1; = p.A68= on NM_031429.2) | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs149960614; called by muse, mutect2, varscan2
